Gene-level copy-number profile of tumor specimen TCGA-CN-4738-01A from TCGA case TCGA-CN-4738, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.7 years (19,621 days).
Specimen TCGA-CN-4738-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.16bef5d8-e815-46bc-b883-c3b10ee16e27.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-4738-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8f7e0b68-0d6d-4009-a8e3-ffa383e3eb63

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 16,624; copy number 2: 39,219; copy number 3: 2,202; copy number 4: 1,503; copy number 5: 111; copy number 6: 109; copy number 17: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-4738-01A-02D-1510-01): tumor purity 0.23, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,856,389–60,856,605, 1 gene: U3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 266 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:17,684,584–29,983,114, 111 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:54,330,670–57,837,046, 155 genes, copy number 6–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,225. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
